Somatic mutation profile of tumor specimen TCGA-17-Z032-01A (aliquot TCGA-17-Z032-01A-01W-0746-08) from TCGA case TCGA-17-Z032, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z032-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cfc4040b-2274-4e37-a6b7-b61bed1b5d95.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z032-11A (Solid Tissue Normal), aliquot TCGA-17-Z032-11A-01W-0746-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/506491ed-0214-44bf-bd00-a74a5e8e31b0

The open-access MAF lists 115 somatic variants for this specimen: 86 protein-altering or splice-affecting, 27 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 70, Silent 27, Nonsense Mutation 10, Frame Shift Del 3, Frame Shift Ins 1, RNA 1, Splice Region 1, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 8/39 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 24/74 reads (32%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- ACVR1B | c.825G>A p.W275* | Nonsense Mutation (SNP) | VAF 13/35 reads (37%) | catalogued as COSV57776965; called by muse, mutect2, varscan2
- AMER1 | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 52/200 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV57659183; called by mutect2, varscan2
- AP1G2 | c.1376G>A p.R459H | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs747117877; called by muse, varscan2
- ASH1L | c.1641C>G p.F547L | Missense Mutation (SNP) | VAF 13/166 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.097); catalogued as COSV64206791; called by muse, mutect2
- CRISP2 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs532707585, COSV59253397; called by mutect2, varscan2
- DNAI2 | c.239del p.G80Afs*6 | Frame Shift Del (DEL) | VAF 18/91 reads (20%) | catalogued as rs745353428; called by mutect2, pindel, varscan2
- EVC | c.178G>C p.D60H | Missense Mutation (SNP) | VAF 59/190 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV53838465; called by muse, mutect2, varscan2
- FADS2 | c.590T>C p.V197A | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0.023); catalogued as rs1325515368; called by muse, mutect2, varscan2
- FAM47B | c.856G>T p.E286* | Nonsense Mutation (SNP) | VAF 102/343 reads (30%) | catalogued as COSV100263974; called by muse, mutect2, varscan2
- FANCL | c.1078C>G p.P360A | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748875030; called by muse, mutect2, varscan2
- FMR1 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 86/268 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99503182; called by muse, varscan2
- GATA1 | c.226C>G p.Q76E | Missense Mutation (SNP) | VAF 124/367 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.08); catalogued as COSV64962141, COSV64963008; called by muse, mutect2, varscan2
- HDAC9 | c.1520A>G p.E507G | Missense Mutation (SNP) | VAF 133/335 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs1267231099; called by muse, mutect2, varscan2
- HRNR | c.2059A>C p.S687R | Missense Mutation (SNP) | VAF 35/158 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.724); catalogued as rs149618092; called by muse, mutect2, varscan2
- IKBKB | c.1066G>T p.E356* | Nonsense Mutation (SNP) | VAF 10/21 reads (48%) | catalogued as COSV60597153; called by muse, mutect2, varscan2
- LAMA2 | c.4001A>G p.Y1334C | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.956); catalogued as rs771297225; called by muse, mutect2, varscan2
- LRP6 | c.739A>G p.I247V | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1454139855; called by muse, mutect2
- MAN1C1 | c.1296dup p.L433Afs*67 | Frame Shift Ins (INS) | VAF 5/38 reads (13%) | catalogued as rs759630213; called by pindel, varscan2
- MGA | c.7312G>T p.E2438* (on ENST00000219905 / NM_001164273.1; = p.E2229* on NM_001080541.2) | Nonsense Mutation (SNP) | VAF 61/122 reads (50%) | catalogued as COSV54953260; called by muse, mutect2, varscan2
- MTOR | c.2870G>A p.R957Q | Missense Mutation (SNP) | VAF 62/174 reads (36%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.938); catalogued as rs1201340871, COSV63873476; called by muse, mutect2, varscan2
- OR1S1 | c.949C>T p.L317F | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.025); catalogued as rs1419457795; called by muse, mutect2
- OR1S2 | c.736G>T p.G246* | Nonsense Mutation (SNP) | VAF 21/85 reads (25%) | catalogued as COSV100224041; called by muse, mutect2, varscan2
- OR51L1 | c.638C>G p.S213* | Nonsense Mutation (SNP) | VAF 12/118 reads (10%) | catalogued as COSV58625417; called by muse, mutect2, varscan2
- PDPR | c.2470A>G p.T824A | Missense Mutation (SNP) | VAF 58/177 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.046); catalogued as rs540523988; called by muse, varscan2
- PHLPP1 | c.4028G>A p.G1343D | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1392954665; called by muse, mutect2, varscan2
- PIGR | c.617T>C p.V206A | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.171); catalogued as rs764862576; called by muse, mutect2, varscan2
- PTEN | c.524T>A p.V175E | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64298898; called by muse, mutect2, varscan2
- SYNE2 | c.8033G>C p.G2678A | Missense Mutation (SNP) | VAF 23/222 reads (10%) | SIFT tolerated (0.69); PolyPhen benign (0.039); catalogued as COSV59955623; called by muse, mutect2, varscan2
- TET1 | c.5290G>A p.E1764K | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.049); catalogued as COSV101017559; called by muse, mutect2, varscan2
- TTC24 | c.1427C>T p.P476L | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); catalogued as rs749271836; called by muse, mutect2, varscan2
- TTYH2 | c.1562C>T p.A521V | Missense Mutation (SNP) | VAF 15/160 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.085); catalogued as rs368866988; called by muse, mutect2
- UBA2 | c.453C>G p.I151M | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV55828683; called by muse, mutect2
- UNC93A | c.52C>T p.L18F | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100023669, COSV57809005; called by muse, mutect2, varscan2
- WDR72 | c.222C>G p.F74L | Missense Mutation (SNP) | VAF 21/185 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100854763; called by muse, mutect2
- WIPI1 | c.1175C>T p.S392L | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as COSV50931814; called by muse, mutect2
- ZFPM2 | c.1868C>T p.T623I | Missense Mutation (SNP) | VAF 54/159 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as rs975845598; called by muse, mutect2, varscan2
- ZNF567 | c.911C>T p.T304I (on ENST00000536254 / NM_001322913.1; = p.T273I on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as rs777758972; called by muse, mutect2, varscan2
- AKAP13 | c.6868G>C p.E2290Q (on ENST00000394518 / NM_007200.5; = p.E2294Q on NM_006738.6) | Missense Mutation (SNP) | VAF 43/208 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BLMH | c.929A>T p.K310M | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- CACNG8 | c.70A>T p.T24S | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- CARNMT1 | c.1138G>T p.E380* | Nonsense Mutation (SNP) | VAF 5/49 reads (10%) | called by muse, mutect2
- CCDC110 | c.2219C>T p.T740I | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- CNTN5 | c.2612C>A p.A871D | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CSMD3 | c.10377G>C p.W3459C (on ENST00000297405 / NM_001363185.1; = p.W3290C on NM_052900.3) | Missense Mutation (SNP) | VAF 9/176 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DGCR2 | c.688A>T p.N230Y | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- DISP3 | c.3224C>T p.P1075L | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DOT1L | c.1150G>T p.A384S | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- EIF3H | c.16G>T p.E6* | Nonsense Mutation (SNP) | VAF 19/55 reads (35%) | called by muse, mutect2, varscan2
- EIF4G3 | c.1676C>G p.S559C | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2
- FAM133A | c.145G>C p.E49Q | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- GLI2 | c.3408del p.V1137* (on ENST00000361492 / NM_001374353.1; = p.V1154* on NM_005270.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | called by mutect2, pindel, varscan2
- GRM6 | c.855C>T p.I285= | Splice Region (SNP) | VAF 6/127 reads (5%) | called by muse, mutect2
- H3C8 | c.277C>G p.L93V | Missense Mutation (SNP) | VAF 85/239 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- IGLV1-40 | c.119C>A p.S40Y | Missense Mutation (SNP) | VAF 68/252 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ITM2C | c.271G>C p.D91H | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- LILRB1 | c.932C>A p.A311D (on ENST00000427581; = p.A275D on NM_006669.6) | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- MBD1 | c.161G>A p.G54D | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MEGF10 | c.893G>A p.C298Y | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYH3 | c.3157A>T p.K1053* | Nonsense Mutation (SNP) | VAF 31/94 reads (33%) | called by muse, mutect2, varscan2
- NLGN4X | c.1759G>T p.V587L | Missense Mutation (SNP) | VAF 112/379 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- OR2A12 | c.558G>T p.L186F | Missense Mutation (SNP) | VAF 121/352 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR2AK2 | c.704C>A p.A235E | Missense Mutation (SNP) | VAF 52/212 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- OR2L3 | c.52C>A p.P18T | Missense Mutation (SNP) | VAF 111/493 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- OR2W3 | c.293C>G p.A98G | Missense Mutation (SNP) | VAF 53/217 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- OR4D10 | c.764T>G p.I255S | Missense Mutation (SNP) | VAF 104/296 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- OR4D5 | c.509G>T p.G170V | Missense Mutation (SNP) | VAF 47/90 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR52E4 | c.868C>A p.P290T | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- OR52E4 | c.869C>A p.P290H | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- OR6F1 | c.354G>T p.M118I | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- POT1 | c.175T>A p.C59S | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRDM14 | c.930T>A p.H310Q | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RCSD1 | c.621G>T p.L207F | Missense Mutation (SNP) | VAF 65/277 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RPL10 | c.197A>C p.E66A | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- SLC45A2 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 66/251 reads (26%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- TENM1 | c.1061G>T p.G354V | Missense Mutation (SNP) | VAF 31/391 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.697); called by muse, mutect2
- TOM1 | c.641del p.P214Rfs*14 | Frame Shift Del (DEL) | VAF 14/91 reads (15%) | called by mutect2, pindel, varscan2
- TRIM58 | c.971A>T p.N324I | Missense Mutation (SNP) | VAF 87/278 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- TRIP11 | c.3433A>T p.T1145S | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TSHZ3 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TUBGCP6 | c.2560G>T p.A854S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.056); called by muse, mutect2
- XIAP | c.573C>A p.Y191* | Nonsense Mutation (SNP) | VAF 11/61 reads (18%) | called by muse, mutect2, varscan2
- ZNF14 | c.1586A>T p.K529M | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF154 | c.455A>T p.Q152L | Missense Mutation (SNP) | VAF 141/454 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- ZNF407 | c.730T>G p.F244V | Missense Mutation (SNP) | VAF 57/119 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- ACADSB | c.132A>T p.I44= | Silent (SNP) | VAF 32/55 reads (58%) | called by muse, mutect2, varscan2
- AGRP | c.138C>G p.G46= | Silent (SNP) | VAF 23/93 reads (25%) | catalogued as COSV52098771; called by muse, mutect2, varscan2
- ALX4 | c.685C>T p.L229= | Silent (SNP) | VAF 110/398 reads (28%) | called by muse, mutect2, varscan2
- CENPF | c.8268C>T p.L2756= | Silent (SNP) | VAF 11/286 reads (4%) | called by muse, mutect2
- CNTN3 | c.2631G>C p.T877= | Silent (SNP) | VAF 21/271 reads (8%) | catalogued as COSV55174636; called by muse, mutect2
- COL4A4 | c.2097G>A p.L699= | Silent (SNP) | VAF 12/96 reads (13%) | called by muse, mutect2, varscan2
- CSMD3 | c.6363G>T p.V2121= (on ENST00000297405 / NM_001363185.1; = p.V2017= on NM_052900.3) | Silent (SNP) | VAF 38/120 reads (32%) | catalogued as COSV52158696, COSV52182456; called by muse, mutect2, varscan2
- DCUN1D2 | c.421C>T p.L141= | Silent (SNP) | VAF 16/256 reads (6%) | called by muse, mutect2
- DDX11 | c.318G>A p.R106= | Silent (SNP) | VAF 29/67 reads (43%) | called by muse, mutect2, varscan2
- DNAAF2 | c.463C>A p.R155= | Silent (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2
- EIF3H | c.15G>A p.K5= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as rs1410215113; called by muse, mutect2, varscan2
- FOXG1 | c.1332G>A p.S444= | Silent (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2, varscan2
- FREM1 | c.441C>T p.F147= | Silent (SNP) | VAF 22/276 reads (8%) | catalogued as COSV66531573; called by muse, mutect2
- H2BC18 | c.198C>T p.F66= | Silent (SNP) | VAF 99/533 reads (19%) | catalogued as rs782409144; called by muse, mutect2, varscan2
- KCND2 | c.1176G>C p.L392= | Silent (SNP) | VAF 20/320 reads (6%) | called by muse, mutect2
- KIF7 | c.1953G>T p.A651= | Silent (SNP) | VAF 55/128 reads (43%) | catalogued as rs764831222; called by muse, mutect2, varscan2
- MYRF | c.906G>A p.P302= (on ENST00000278836 / NM_001127392.3; = p.P293= on NM_013279.4) | Silent (SNP) | VAF 45/107 reads (42%) | catalogued as rs576057213; called by muse, mutect2, varscan2
- NLGN4X | c.2052G>T p.S684= | Silent (SNP) | VAF 62/247 reads (25%) | catalogued as COSV52015727; called by muse, mutect2, varscan2
- PCDHA11 | c.1092C>T p.P364= | Silent (SNP) | VAF 27/77 reads (35%) | called by muse, mutect2, varscan2
- POTEF | c.2424C>A p.A808= | Silent (SNP) | VAF 66/186 reads (35%) | called by muse, varscan2
- RABGAP1L | c.444A>G p.E148= | Silent (SNP) | VAF 128/444 reads (29%) | called by mutect2, varscan2
- ROCK2 | c.682C>T p.L228= | Silent (SNP) | VAF 52/203 reads (26%) | called by muse, mutect2, varscan2
- RYR3 | c.1731G>A p.A577= | Silent (SNP) | VAF 18/93 reads (19%) | catalogued as rs776461221, COSV66779569; called by muse, mutect2, varscan2
- SERPINB10 | c.757C>T p.L253= | Silent (SNP) | VAF 103/183 reads (56%) | catalogued as rs746489069; called by muse, mutect2, varscan2
- TMSB10 | c.33C>G p.A11= | Silent (SNP) | VAF 15/54 reads (28%) | called by muse, mutect2, varscan2
- TRAF3IP1 | c.262C>T p.L88= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as rs1298230250; called by muse, mutect2, varscan2
- ZBED1 | c.1410C>T p.N470= | Silent (SNP) | VAF 8/138 reads (6%) | catalogued as rs141520513, COSV58138564; called by muse, mutect2
- AC016747.4 | n.483A>G | RNA (SNP) | VAF 4/64 reads (6%) | catalogued as rs1381170020; called by muse, mutect2
- TENM4 | c.-321+38451G>T | Intron (SNP) | VAF 9/31 reads (29%) | called by muse, mutect2, varscan2
